Somatic mutation profile of tumor specimen TCGA-77-A5GH-01A (aliquot TCGA-77-A5GH-01A-11D-A27K-08) from TCGA case TCGA-77-A5GH, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 81.7 years (29,843 days).
Specimen TCGA-77-A5GH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6884a64e-742d-4e3e-ba5c-58274258e513.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-A5GH-10A (Blood Derived Normal), aliquot TCGA-77-A5GH-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/064acb51-15b3-4658-940d-7590204dfcbc

The open-access MAF lists 277 somatic variants for this specimen: 212 protein-altering or splice-affecting, 64 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 64, Nonsense Mutation 11, Frame Shift Del 6, Splice Site 4, Frame Shift Ins 3, Splice Region 2, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 42/151 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTR | c.236C>A p.T79K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs730881163, CM1310453, CM951252, COSV52702116, COSV99379633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1209C>A p.F403L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as rs994791007, COSV99286745; called by muse, mutect2, varscan2
- ABCA9 | c.3410G>C p.G1137A | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV100383430; called by muse, mutect2, varscan2
- ABL2 | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV100859677; called by muse, varscan2
- ACY3 | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.182); catalogued as COSV99663137; called by muse, mutect2, varscan2
- ADA2 | c.1204G>A p.D402N (on ENST00000262607; = p.D161N on NM_177405.3) | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99376415; called by muse, mutect2, varscan2
- ADCY8 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV99651378; called by muse, mutect2, varscan2
- ADGRG4 | c.2906C>G p.S969C | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99796570; called by muse, mutect2, varscan2
- ADGRV1 | c.13527G>C p.K4509N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV101316428; called by muse, mutect2
- AGL | c.4091A>G p.D1364G | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99649969; called by muse, mutect2, varscan2
- ALOX15B | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101205701; called by muse, mutect2, varscan2
- ARHGAP36 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV52269709, COSV99358163; called by muse, mutect2, varscan2
- ARHGAP4 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1380501731, COSV100604214; called by muse, mutect2, varscan2
- ASPM | c.9935G>T p.C3312F | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99661008; called by muse, mutect2, varscan2
- ATP10B | c.2313G>C p.K771N | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100515662; called by muse, mutect2
- ATP6V1C1 | c.382-1G>A p.X128_splice | Splice Site (SNP) | VAF 47/210 reads (22%) | catalogued as COSV101215137, COSV67778773; called by muse, mutect2, varscan2
- AVPR1A | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100146906; called by muse, mutect2, varscan2
- BTBD8 | c.672G>T p.L224F | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100730457; called by muse, mutect2, varscan2
- C8orf34 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs540019285, COSV100447804; called by muse, mutect2
- CCDC136 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV99923120; called by muse, mutect2, varscan2
- CCDC54 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs757767034, COSV53759634; called by muse, mutect2, varscan2
- CES5A | c.940G>T p.V314F | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99307982; called by muse, mutect2, varscan2
- CFAP221 | c.1054A>G p.T352A | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV54659072; called by muse, mutect2, varscan2
- CILP2 | c.1987G>T p.V663L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs779074968, COSV99365142; called by muse, mutect2, varscan2
- CNST | c.231G>C p.L77F | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV100829919; called by muse, mutect2, varscan2
- COL15A1 | c.2760G>T p.K920N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100897958; called by muse, mutect2, varscan2
- CSMD1 | c.3310G>A p.E1104K (on ENST00000520002; = p.E1103K on NM_033225.6) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs369340916; called by muse, mutect2, varscan2
- CSMD3 | c.11006A>G p.E3669G (on ENST00000297405 / NM_001363185.1; = p.E3500G on NM_052900.3) | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99846213; called by muse, mutect2, varscan2
- CTNNA2 | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1175614546, COSV100561923; called by muse, mutect2, varscan2
- DAPP1 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs908547761, COSV56453639, COSV99597210; called by muse, mutect2
- DCLRE1A | c.984C>G p.S328R | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100800476; called by muse, mutect2, varscan2
- DCTPP1 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100073633; called by muse, mutect2
- DDX55 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs965577416, COSV99434790; called by muse, mutect2, varscan2
- DDX59 | c.1235T>G p.L412R | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV100494690; called by muse, mutect2, varscan2
- DGKG | c.2036T>C p.V679A | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.278); catalogued as COSV99404258; called by muse, mutect2
- DIAPH2 | c.3010-2A>G p.X1004_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100235024; called by muse, mutect2
- DIP2C | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV99793559; called by muse, mutect2, varscan2
- DKK1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138015066; called by mutect2, varscan2
- DLGAP3 | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV99333132; called by muse, mutect2, varscan2
- DNAH8 | c.9116C>G p.P3039R | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547037; called by muse, mutect2, varscan2
- DOCK2 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV99915005; called by muse, mutect2, varscan2
- DOK6 | c.738G>C p.R246= | Splice Region (SNP) | VAF 39/208 reads (19%) | catalogued as COSV101234956; called by muse, mutect2, varscan2
- DSEL | c.3296C>G p.S1099* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as COSV100025681, COSV100026052; called by muse, mutect2, varscan2
- DSP | c.1367G>A p.R456K | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV101131711; called by muse, mutect2, varscan2
- DSP | c.6992C>G p.S2331C | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101131712; called by muse, mutect2
- DTNA | c.1499C>G p.A500G | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99314965; called by muse, mutect2, varscan2
- DYSF | c.5098C>T p.Q1700* | Nonsense Mutation (SNP) | VAF 14/304 reads (5%) | catalogued as CD1414213, COSV99247804; called by muse, mutect2
- DZIP1 | c.1432G>A p.A478T (on ENST00000347108; = p.A459T on NM_014934.5) | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100714076, COSV100714180; called by muse, mutect2, varscan2
- EARS2 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54843036, COSV54843089; called by muse, mutect2, varscan2
- EDEM3 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV100545571; called by muse, mutect2, varscan2
- EFNA4 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV99665294; called by muse, mutect2, varscan2
- EGR2 | c.778C>G p.P260A | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV54348658, COSV99654280; called by muse, mutect2
- ELFN2 | c.1880A>T p.K627M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV101297623; called by muse, mutect2, varscan2
- EMILIN1 | c.1868G>T p.R623L | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV53153274, COSV99566518; called by muse, mutect2, varscan2
- EP400 | c.2677C>G p.L893V | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100202134; called by muse, mutect2, varscan2
- EXOSC9 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs1465112221, COSV99697136; called by muse, mutect2, varscan2
- EXTL2 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as COSV100921137; called by muse, mutect2, varscan2
- EYA2 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100427274; called by muse, mutect2
- FAM124A | c.1180G>A p.E394K (on ENST00000322475 / NM_001242312.2; = p.E430K on NM_145019.4) | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV99696445; called by muse, mutect2, varscan2
- FAM166A | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61117549; called by muse, mutect2, varscan2
- FAM53A | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV100357277; called by muse, mutect2, varscan2
- FAM83A | c.718A>T p.I240F | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99414561; called by muse, mutect2, varscan2
- FAT1 | c.3487G>C p.A1163P | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499624, COSV71671920; called by muse, mutect2, varscan2
- FAT4 | c.12934G>T p.G4312W | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.591); catalogued as COSV100629973; called by muse, mutect2, varscan2
- FLG2 | c.1355C>T p.T452I | Missense Mutation (SNP) | VAF 39/436 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs939394823, COSV101166169, COSV66167899; called by muse, mutect2
- FNIP1 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761595163, COSV57194596; called by muse, mutect2, varscan2
- FOXM1 | c.1895T>G p.V632G | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100700900; called by muse, mutect2, varscan2
- FZD8 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101020263; called by muse, mutect2, varscan2
- GABRA4 | c.803T>A p.I268N | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99974610; called by muse, mutect2, varscan2
- GALNT10 | c.824G>C p.R275P | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.279); catalogued as rs781588576, COSV51727260; called by muse, mutect2, varscan2
- GBP2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.077); catalogued as COSV100975428; called by muse, mutect2, varscan2
- GJA10 | c.966G>T p.W322C | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101005433; called by muse, mutect2, varscan2
- GLE1 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.151); catalogued as rs771547725, COSV59410563; called by muse, mutect2, varscan2
- GOT2 | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99803952; called by muse, mutect2, varscan2
- GPC3 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100893509; called by muse, mutect2, varscan2
- GPLD1 | c.2258G>C p.G753A | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.642); catalogued as COSV100015558, COSV57757238; called by muse, mutect2, varscan2
- GRIN3A | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs777855692, COSV100701771, COSV62457886; called by muse, mutect2, varscan2
- H2AC13 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as rs768930206, COSV100704420, COSV100704432; called by muse, mutect2
- HDAC9 | c.2350G>T p.A784S | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101287306; called by muse, mutect2, varscan2
- HERC4 | c.2360A>C p.K787T (on ENST00000395198 / NM_022079.3; = p.K779T on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV99517406; called by muse, mutect2, varscan2
- HGD | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99381375; called by muse, mutect2, varscan2
- HHIPL2 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 19/438 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.516); catalogued as COSV100596958, COSV100597058; called by muse, mutect2
- HUWE1 | c.4165A>G p.M1389V | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs782093160, COSV99474039; called by muse, mutect2, varscan2
- ICE1 | c.4486G>A p.V1496I | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750791646, COSV99665591; called by muse, mutect2
- IMPG2 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV99516361; called by muse, mutect2, varscan2
- JUND | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV99417295; called by muse, mutect2
- KAT6A | c.1599-1G>T p.X533_splice | Splice Site (SNP) | VAF 25/50 reads (50%) | catalogued as rs181883998, COSV99705795; called by muse, mutect2, varscan2
- KCNA7 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV99672015; called by muse, mutect2
- KCND2 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100478295, COSV58572707; called by muse, mutect2, varscan2
- KCNK7 | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100442362; called by muse, mutect2, varscan2
- KCNQ1 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); catalogued as COSV99328300; called by muse, mutect2, varscan2
- KIAA1549L | c.5377C>A p.L1793M (on ENST00000321505; = p.L2090M on NM_012194.3) | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100382260; called by muse, mutect2, varscan2
- KIF13A | c.317C>G p.S106W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99437916; called by muse, mutect2, varscan2
- KRIT1 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.43); catalogued as COSV100388921; called by muse, mutect2, varscan2
- LGR6 | c.444C>A p.N148K (on ENST00000367278 / NM_001017403.1; = p.N96K on NM_021636.3) | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707771; called by muse, mutect2, varscan2
- LIN28B | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as COSV61498149; called by muse, mutect2
- LMF2 | c.2036A>G p.Q679R | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs762048091, COSV99327760; called by muse, mutect2, varscan2
- LPXN | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs749006421, COSV101223126; called by muse, mutect2, varscan2
- LRCH1 | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV60845415; called by muse, mutect2
- LRRC1 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1314630463, COSV100906063; called by muse, mutect2, varscan2
- LRRC32 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760271590, COSV99477271; called by muse, varscan2
- MAP3K19 | c.2465G>C p.R822T | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV100209191; called by muse, mutect2
- MATN4 | c.888G>C p.R296S (on ENST00000372754; = p.R255S on NM_003833.4) | Missense Mutation (SNP) | VAF 80/388 reads (21%) | PolyPhen benign (0.001); catalogued as COSV100637160; called by muse, varscan2
- METTL22 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 260/666 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV50838007, COSV99371877; called by muse, varscan2
- MGAT5B | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100048867; called by muse, mutect2, varscan2
- MKI67 | c.6304G>T p.A2102S | Missense Mutation (SNP) | VAF 133/743 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100896942; called by muse, mutect2, varscan2
- MTSS2 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100116683; called by muse, mutect2
- MUS81 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 106/617 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as rs1435673037, COSV100337383; called by muse, mutect2, varscan2
- MYH13 | c.1527G>C p.E509D | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99355298; called by muse, mutect2, varscan2
- NADK | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.934); catalogued as COSV100411040; called by muse, mutect2, varscan2
- NAV3 | c.3451G>T p.G1151C | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99894971; called by muse, mutect2, varscan2
- NFATC1 | c.2762A>G p.D921G (on ENST00000427363 / NM_001278669.2; = p.D908G on NM_172387.3) | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99502439; called by muse, mutect2, varscan2
- NHSL2 | c.713C>T p.S238F (on ENST00000510661; = p.S604F on NM_001013627.2) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1461719576, COSV101030310; called by muse, mutect2, varscan2
- NLRP3 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV60223047; called by muse, mutect2, varscan2
- NLRP9 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100242612, COSV100243374; called by muse, mutect2, varscan2
- NLRP9 | c.501G>T p.L167F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100243378; called by muse, mutect2, varscan2
- NOP2 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs763386179, COSV58904828, COSV58908135; called by muse, mutect2
- NOTCH2 | c.5360G>T p.R1787L | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56685015, COSV99866574; called by muse, mutect2, varscan2
- NPAS2 | c.1937A>G p.N646S | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100176880; called by muse, mutect2, varscan2
- OR10A4 | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs888704600, COSV65842423; called by muse, mutect2, varscan2
- OR10J5 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58387121; called by muse, mutect2, varscan2
- OR10Q1 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV100372100, COSV100372383; called by muse, mutect2, varscan2
- OR4C11 | c.830C>G p.T277R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100155489, COSV56354878; called by muse, mutect2, varscan2
- OR5K3 | c.965G>C p.*322Sext*? | Nonstop Mutation (SNP) | VAF 50/247 reads (20%) | catalogued as COSV101051680, COSV67349654; called by muse, mutect2, varscan2
- OR5M1 | c.919G>T p.G307* | Nonsense Mutation (SNP) | VAF 76/345 reads (22%) | catalogued as COSV101591606, COSV73202170; called by muse, mutect2, varscan2
- OR7A10 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.142); catalogued as COSV99932520; called by muse, mutect2, varscan2
- OR7A10 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as COSV99932522; called by muse, mutect2, varscan2
- PACSIN2 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 55/145 reads (38%) | catalogued as COSV99606639; called by muse, mutect2, varscan2
- PAPPA2 | c.2159C>A p.A720E | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100867092; called by muse, mutect2, varscan2
- PARP10 | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 37/622 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1267771144, COSV100478296; called by muse, mutect2
- PCDH11X | c.1945G>T p.G649C | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014687; called by muse, mutect2, varscan2
- PDGFRA | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV99957522; called by muse, mutect2, varscan2
- PDGFRA | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99957524; called by muse, mutect2
- PEG3 | c.3546G>C p.Q1182H | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55632835, COSV99690237; called by muse, mutect2, varscan2
- PFKFB3 | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 89/408 reads (22%) | PolyPhen probably damaging (0.987); catalogued as COSV100432339; called by muse, mutect2, varscan2
- PGAM2 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as COSV99803888; called by muse, mutect2
- PIP5K1C | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 97/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100095990; called by muse, mutect2, varscan2
- PLG | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 8/87 reads (9%) | catalogued as COSV99805065; called by muse, mutect2, varscan2
- PLPP2 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 99/264 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756299365, COSV54119575, COSV99514812; called by muse, mutect2, varscan2
- PLS1 | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV100538308; called by muse, mutect2, varscan2
- PLXNA4 | c.4291G>T p.E1431* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | catalogued as COSV100326670; called by muse, mutect2, varscan2
- PODN | c.562A>G p.K188E (on ENST00000395871; = p.K140E on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/480 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100439801; called by muse, varscan2
- PPIC | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as rs1235793920, COSV100120625; called by muse, mutect2, varscan2
- PPP2R2C | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as rs1175331044, COSV59448324; called by muse, mutect2, varscan2
- PRDM15 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1439857070, COSV54159085; called by muse, mutect2, varscan2
- PRR19 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); catalogued as COSV100004095; called by muse, mutect2, varscan2
- PRRC1 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99688120; called by muse, mutect2, varscan2
- PTPRK | c.2125A>T p.I709F | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100951519; called by muse, mutect2, varscan2
- PUS1 | c.565G>T p.G189W | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100435280; called by muse, mutect2, varscan2
- PXDNL | c.3491C>T p.S1164L | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.439); catalogued as COSV100686011; called by muse, mutect2
- RABGAP1 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV101017145; called by muse, mutect2, varscan2
- RC3H1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99281689, COSV99281711; called by muse, mutect2, varscan2
- RD3 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100879228; called by muse, mutect2, varscan2
- REG3G | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99709675; called by muse, mutect2, varscan2
- RGS22 | c.3698A>T p.K1233M | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100693727; called by muse, mutect2
- RNASET2 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99218655; called by muse, mutect2, varscan2
- RNF19A | c.2176A>C p.S726R | Missense Mutation (SNP) | VAF 156/339 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100348078; called by muse, mutect2, varscan2
- ROBO3 | c.3796G>T p.D1266Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1407834516, COSV100127840, COSV60622878; called by muse, mutect2, varscan2
- RUNX1T1 | c.394A>G p.T132A (on ENST00000265814 / NM_001198628.1; = p.T105A on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as rs1456444144, COSV56168359; called by muse, mutect2, varscan2
- RYR2 | c.4751C>A p.P1584Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63682006, COSV63692099; called by muse, mutect2, varscan2
- SALL3 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101610048; called by muse, mutect2, varscan2
- SHANK1 | c.2693G>T p.R898I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV99521929; called by muse, mutect2, varscan2
- SHANK2 | c.2045G>T p.G682V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99575863; called by muse, mutect2, varscan2
- SIRPG | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 91/309 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.445); catalogued as COSV99403957; called by muse, mutect2, varscan2
- SLC22A11 | c.1590G>A p.Q530= | Splice Region (SNP) | VAF 36/195 reads (18%) | catalogued as COSV100102647; called by muse, mutect2, varscan2
- SLC24A2 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53863669, COSV99647366; called by muse, mutect2, varscan2
- SLC43A3 | c.1160T>G p.I387S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV100725261; called by muse, mutect2, varscan2
- SLC8A1 | c.1063A>T p.S355C | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV100247300; called by muse, mutect2, varscan2
- SNRNP70 | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as COSV99672451; called by muse, mutect2
- SNX11 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV63658562; called by muse, mutect2
- SNX22 | c.257A>C p.Y86S | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100254706; called by muse, mutect2, varscan2
- SPI1 | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV57047695, COSV99909229; called by muse, mutect2
- SPIDR | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as rs535412315, COSV99855971; called by muse, mutect2, varscan2
- ST18 | c.1118G>A p.C373Y | Missense Mutation (SNP) | VAF 217/407 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99390904; called by muse, mutect2, varscan2
- STAT5A | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.048); catalogued as COSV100604797; called by muse, mutect2, varscan2
- SVIL | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 52/274 reads (19%) | catalogued as COSV100881512; called by muse, mutect2, varscan2
- SYCP2 | c.3518G>C p.S1173T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV100698427; called by muse, mutect2, varscan2
- SYT1 | c.1132T>C p.F378L | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV99697233; called by muse, mutect2, varscan2
- SYT9 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as COSV100609031, COSV59615202; called by muse, mutect2, varscan2
- TAS2R10 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as rs773805245, COSV53701605, COSV99555616; called by muse, mutect2, varscan2
- TCF12 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99978821; called by muse, mutect2, varscan2
- TCF4 | c.1031A>G p.N344S | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.063); catalogued as COSV100610772; called by muse, mutect2
- TFAM | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV65877542; called by muse, mutect2, varscan2
- TFAP2C | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV99571755; called by muse, mutect2, varscan2
- TNN | c.1234+1G>A p.X412_splice | Splice Site (SNP) | VAF 41/140 reads (29%) | catalogued as COSV99512862; called by muse, mutect2, varscan2
- TOPBP1 | c.526T>A p.W176R | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99605787; called by muse, mutect2, varscan2
- TOR1A | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.393); catalogued as COSV100693983; called by muse, varscan2
- TOX | c.1429A>G p.N477D | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV63848644; called by muse, mutect2, varscan2
- TRAPPC6A | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99135364; called by muse, mutect2, varscan2
- USH2A | c.11095G>T p.E3699* | Nonsense Mutation (SNP) | VAF 43/233 reads (18%) | catalogued as CM149929, COSV100241748; called by muse, mutect2, varscan2
- USH2A | c.6478C>G p.H2160D | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100241751; called by muse, mutect2, varscan2
- USP48 | c.3091G>T p.G1031C | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs551252073, COSV100379514, COSV100380218; called by muse, mutect2, varscan2
- USP6 | c.2848C>G p.Q950E | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.212); catalogued as COSV100004822; called by muse, mutect2, varscan2
- VCL | c.2600A>G p.E867G | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.988); catalogued as COSV99281280; called by muse, mutect2, varscan2
- VPS13C | c.6554C>T p.T2185M (on ENST00000644861 / NM_020821.3; = p.T2142M on NM_017684.5) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs146858303, COSV99827441; called by muse, mutect2, varscan2
- XKR4 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 76/438 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59313675; called by muse, mutect2, varscan2
- XKR8 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 40/187 reads (21%) | catalogued as COSV100871906, COSV100872179; called by muse, mutect2, varscan2
- ZC3H13 | c.3776C>G p.P1259R | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99667406, COSV99668829; called by muse, mutect2
- ZNF28 | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100354697; called by muse, mutect2, varscan2
- ZNF493 | c.1497A>C p.K499N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100828898; called by mutect2, varscan2
- ZNF772 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100582919; called by muse, varscan2
- ZSCAN30 | c.1055G>C p.S352T | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.068); catalogued as COSV99735124; called by muse, mutect2, varscan2
- AGAP1 | c.591del p.K197Nfs*6 | Frame Shift Del (DEL) | VAF 99/379 reads (26%) | called by mutect2, pindel, varscan2
- CASZ1 | c.926_936del p.A309Gfs*142 | Frame Shift Del (DEL) | VAF 87/362 reads (24%) | called by mutect2, pindel, varscan2
- CDON | c.777del p.Q260Rfs*40 | Frame Shift Del (DEL) | VAF 29/155 reads (19%) | called by mutect2, pindel, varscan2
- COL4A1 | c.3218del p.G1073Vfs*124 | Frame Shift Del (DEL) | VAF 72/501 reads (14%) | called by mutect2, pindel, varscan2
- ILDR2 | c.426_427dup p.Y143Sfs*132 | Frame Shift Ins (INS) | VAF 38/135 reads (28%) | called by mutect2, pindel, varscan2
- KCNK2 | c.576dup p.G193Wfs*21 (on ENST00000444842 / NM_001017425.3; = p.G178Wfs*21 on NM_014217.4) | Frame Shift Ins (INS) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- OR5H1 | c.717dup p.T240Hfs*30 | Frame Shift Ins (INS) | VAF 50/206 reads (24%) | called by mutect2, pindel, varscan2
- PDE6B | c.122del p.P41Rfs*109 | Frame Shift Del (DEL) | VAF 25/155 reads (16%) | called by mutect2, pindel, varscan2
- S1PR1 | c.489_502del p.I164Gfs*81 | Frame Shift Del (DEL) | VAF 28/220 reads (13%) | called by mutect2, pindel
- ADCY2 | c.1234T>C p.L412= | Silent (SNP) | VAF 23/349 reads (7%) | catalogued as COSV100603953; called by muse, mutect2
- ADD2 | c.1059G>T p.G353= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100036405; called by muse, mutect2, varscan2
- AGO2 | c.480G>A p.Q160= | Silent (SNP) | VAF 20/312 reads (6%) | catalogued as COSV99596321; called by muse, mutect2
- AMER3 | c.1446C>G p.G482= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100366859; called by muse, mutect2, varscan2
- BCKDHB | c.912G>A p.L304= | Silent (SNP) | VAF 55/226 reads (24%) | catalogued as COSV100244037; called by muse, mutect2, varscan2
- C14orf39 | c.633A>G p.K211= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100408070; called by muse, varscan2
- CAPN15 | c.2137C>T p.L713= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as COSV99562795; called by muse, mutect2, varscan2
- CATSPER1 | c.1683G>A p.R561= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100376214; called by muse, mutect2, varscan2
- CD3G | c.132G>A p.L44= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as COSV99416881; called by muse, mutect2, varscan2
- CD79B | c.516C>T p.F172= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV50077337; called by muse, mutect2, varscan2
- CDKL5 | c.2685G>A p.P895= | Silent (SNP) | VAF 71/152 reads (47%) | catalogued as COSV101184133; called by muse, mutect2, varscan2
- CHD7 | c.8424C>T p.N2808= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs773594482, COSV71107196; called by muse, mutect2, varscan2
- CKM | c.279C>T p.I93= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV99675677; called by muse, mutect2, varscan2
- CLPB | c.249C>G p.L83= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV53628020, COSV53632212, COSV99577898; called by muse, mutect2
- CSMD2 | c.7653C>T p.T2551= | Silent (SNP) | VAF 30/172 reads (17%) | catalogued as COSV53900773, COSV99594677; called by muse, mutect2, varscan2
- CSTF1 | c.66G>A p.L22= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV99410341; called by muse, mutect2, varscan2
- CTDP1 | c.975C>T p.G325= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as rs1434273990, COSV99311060; called by muse, mutect2, varscan2
- CYP2C18 | c.510G>T p.L170= | Silent (SNP) | VAF 60/276 reads (22%) | catalogued as COSV99608912; called by muse, mutect2, varscan2
- CYP4F8 | c.696A>T p.V232= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100358221; called by muse, mutect2, varscan2
- DACH2 | c.589C>T p.L197= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100913820; called by muse, mutect2, varscan2
- DGLUCY | c.1749C>A p.G583= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99824692; called by muse, mutect2, varscan2
- DNAAF3 | c.186G>T p.R62= (on ENST00000524407 / NM_001256715.2; = p.R109= on NM_178837.4) | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV101200201, COSV101200207; called by muse, mutect2, varscan2
- DNAH2 | c.1770C>A p.A590= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV99318535; called by muse, mutect2, varscan2
- DOCK4 | c.3777C>T p.I1259= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as COSV69854422; called by muse, mutect2
- DOCK6 | c.2925G>C p.V975= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99626555, COSV99626850; called by muse, mutect2, varscan2
- DQX1 | c.1080G>C p.V360= | Silent (SNP) | VAF 111/467 reads (24%) | catalogued as COSV101099201; called by muse, mutect2, varscan2
- DUSP11 | c.696C>T p.C232= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99731229; called by muse, varscan2
- ERICH3 | c.1854A>G p.S618= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV100445542; called by muse, mutect2, varscan2
- EVA1A | c.327G>A p.K109= | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as rs1245797476, COSV99285884; called by muse, mutect2, varscan2
- FBXL17 | c.1398C>G p.L466= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as COSV100672635; called by muse, mutect2
- GAD2 | c.1143G>T p.L381= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV99393956; called by muse, mutect2, varscan2
- INPP5B | c.297C>T p.V99= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV100886250; called by muse, mutect2
- KCNJ11 | c.210C>T p.H70= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV100379210; called by muse, mutect2, varscan2
- KMT2C | c.1111C>T p.L371= | Silent (SNP) | VAF 23/727 reads (3%) | catalogued as COSV100076046; called by muse, mutect2
- MUC16 | c.38916C>T p.F12972= | Silent (SNP) | VAF 27/339 reads (8%) | catalogued as rs374640134, COSV101199103; called by muse, mutect2
- MUC5B | c.5280C>A p.T1760= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as rs759778109, COSV101500708, COSV71591785; called by muse, mutect2, varscan2
- NEFH | c.2376G>A p.E792= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as COSV100151782; called by muse, mutect2, varscan2
- NLRP13 | c.1152A>G p.T384= | Silent (SNP) | VAF 54/199 reads (27%) | catalogued as COSV100738478; called by muse, mutect2, varscan2
- OR10A4 | c.297C>A p.A99= | Silent (SNP) | VAF 42/217 reads (19%) | catalogued as COSV101139590; called by muse, mutect2, varscan2
- OR2A2 | c.354C>T p.S118= | Silent (SNP) | VAF 54/231 reads (23%) | catalogued as rs1408036779, COSV101286669; called by muse, mutect2, varscan2
- OR4B1 | c.765C>G p.L255= | Silent (SNP) | VAF 15/157 reads (10%) | catalogued as COSV100535700, COSV58882670; called by muse, mutect2, varscan2
- OR56A4 | c.450A>T p.P150= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs757389999, COSV58110040; called by muse, mutect2
- OR5B21 | c.309G>T p.V103= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs1270458928, COSV100835185; called by muse, mutect2, varscan2
- OR5M3 | c.660C>T p.L220= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as COSV100392675, COSV56566908; called by muse, mutect2
- ORC3 | c.1092A>G p.E364= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100006235; called by muse, mutect2, varscan2
- POGK | c.618G>T p.L206= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100902587; called by muse, mutect2
- PPP1R7 | c.846A>G p.A282= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV99298174; called by muse, mutect2, varscan2
- PRRC2C | c.5101C>A p.R1701= (on ENST00000367742; = p.R1699= on NM_015172.4) | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1400478151, COSV100145948; called by muse, mutect2, varscan2
- RBM4 | c.69G>A p.E23= | Silent (SNP) | VAF 62/321 reads (19%) | catalogued as COSV100029731; called by muse, mutect2, varscan2
- RCBTB2 | c.330T>C p.H110= | Silent (SNP) | VAF 28/292 reads (10%) | catalogued as COSV100749641; called by muse, mutect2
- S1PR1 | c.327C>T p.T109= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV100541650; called by muse, mutect2, varscan2
- SASH1 | c.3585C>T p.A1195= | Silent (SNP) | VAF 71/355 reads (20%) | catalogued as rs141140730; called by muse, mutect2, varscan2
- SEC16A | c.4110C>A p.L1370= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99260091; called by muse, mutect2
- SLC17A8 | c.489C>T p.A163= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs750296539, COSV100035832; called by muse, mutect2, varscan2
- SLC17A8 | c.1035T>C p.F345= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV100035834; called by muse, mutect2, varscan2
- SLC23A2 | c.618C>T p.H206= | Silent (SNP) | VAF 73/337 reads (22%) | catalogued as rs1270231890, COSV100595258; called by muse, mutect2, varscan2
- SLITRK3 | c.2436G>T p.L812= | Silent (SNP) | VAF 44/285 reads (15%) | catalogued as COSV99579984; called by muse, mutect2, varscan2
- SORCS3 | c.2502G>T p.V834= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV100863786; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.745A>C p.R249= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV100085095; called by muse, mutect2
- STAB2 | c.3684T>C p.Y1228= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV101186269; called by muse, mutect2, varscan2
- SYTL5 | c.234A>G p.G78= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV99937585; called by muse, mutect2, varscan2
- TRIO | c.3642G>T p.A1214= | Silent (SNP) | VAF 26/680 reads (4%) | catalogued as COSV100710890, COSV60078251; called by muse, mutect2
- TULP4 | c.153G>A p.G51= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV100893798; called by muse, mutect2, varscan2
- USP13 | c.561A>T p.P187= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV99831689; called by muse, mutect2, varscan2
- RBMX | c.109+70T>C | Intron (SNP) | VAF 52/131 reads (40%) | catalogued as COSV100284924; called by muse, mutect2, varscan2
